Somatic mutation profile of tumor specimen 0DVDUD from CCDI case PBCMPD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DVDUD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07bd2233-6581-45ae-af5a-6656a4133be1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVDV0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37fdd6dc-b579-4ea2-aebb-eb674d047c5b

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, 3'UTR 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 138/469 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATXN3 | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749230434; called by mutect2, varscan2
- GALNT12 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 29/521 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777425926, COSV100899124; called by muse, mutect2
- GANAB | c.1681C>A p.Q561K | Missense Mutation (SNP) | VAF 120/423 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs538664830; called by muse, mutect2, varscan2
- NECTIN2 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 111/279 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as COSV52976102; called by muse, varscan2
- TNXB | c.6652G>A p.E2218K (on ENST00000647633; = p.E1971K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/360 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); catalogued as rs1388279498, COSV64484397; called by muse, mutect2, varscan2
- TTN | c.84788G>A p.R28263H (on ENST00000591111; = p.R20839H on NM_003319.4) | Missense Mutation (SNP) | VAF 131/389 reads (34%) | PolyPhen probably damaging (0.998); catalogued as rs397517744, COSV100593212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF471 | c.339C>A p.S113R | Missense Mutation (SNP) | VAF 118/315 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs760949533; called by muse, mutect2, varscan2
- APOL1 | c.554C>A p.S185Y | Missense Mutation (SNP) | VAF 155/414 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CLEC10A | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 197/552 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- DENND2B | c.2941-3C>A | Splice Region (SNP) | VAF 54/378 reads (14%) | called by mutect2, varscan2
- PLPPR4 | c.1945T>C p.W649R | Missense Mutation (SNP) | VAF 128/379 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPRC1 | c.95G>A p.W32* | Nonsense Mutation (SNP) | VAF 85/267 reads (32%) | called by muse, mutect2, varscan2
- ATP6V0E2 | c.*455G>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- PON3 | c.778-34G>T | Intron (SNP) | VAF 35/101 reads (35%) | catalogued as rs1157123773; called by muse, mutect2, varscan2
- SYMPK | c.848-53C>A | Intron (SNP) | VAF 37/99 reads (37%) | called by muse, mutect2, varscan2
